Gene-level copy-number profile of tumor specimen ALCH-B3FR-TTP1-A from ALCHEMIST case ALCH-B3FR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.7 years (23,278 days).
Specimen ALCH-B3FR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d062f693-3a08-4f58-90de-8d9eeba58454.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3FR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/30012373-862f-41a5-b48c-2e6c148ebb85

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 15,927; copy number 2: 41,658; copy number 3: 301; copy number 4: 169; copy number 5: 182; copy number 6: 52; copy number 7: 1; copy number 8: 41; copy number 9: 2; copy number 10: 3; copy number 11: 11; copy number 25: 2; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:760,911–761,989, 1 gene: AL669831.2.
- chr1:904,834–915,976, 1 gene (within-gene range 0–1): AL645608.6.
- chr1:944,203–965,719, 2 genes (within-gene range 0–4): NOC2L, KLHL17.
- chr1:20,664,014–20,732,837, 3 genes: KIF17, AL663074.2, SH2D5.
- chr1:21,217,247–21,345,572, 3 genes: ECE1, AL031005.1, ECE1-AS1.
- chr2:10,021,578–10,022,825, 1 gene: AC104794.4.
- chr7:140,404,058–140,427,974, 1 gene (within-gene range 0–2): RAB19.
- chr7:149,069,641–149,126,324, 3 genes: ZNF786, ZNF425, RN7SL521P.
- chr9:121,444,991–121,500,027, 2 genes (within-gene range 0–1): GGTA1, RN7SL187P.
- chr11:71,448,674–71,452,157, 1 gene (within-gene range 0–1): AP002387.1.
- chr11:71,473,503–71,473,568, 1 gene (within-gene range 0–1): MIR6754.
- chr12:132,200,436–132,201,287, 1 gene (within-gene range 0–3): AC138466.4.
- chr14:74,614,693–74,616,647, 1 gene: AC013451.2.
- chr16:81,100,875–81,220,370, 3 genes (within-gene range 0–2): PKD1L2, RNU6-1191P, AC092718.9.
- chr16:83,929,796–83,931,223, 1 gene (within-gene range 0–2): AC009119.2.
- chr16:89,969,773–89,972,832, 1 gene (within-gene range 0–1): CENPBD1.
- chr19:38,108,500–38,109,533, 1 gene (within-gene range 0–1): AC011465.1.
- chr19:48,118,432–48,127,706, 1 gene (within-gene range 0–1): AC011466.3.
- chr20:56,522,252–56,731,460, 9 genes (within-gene range 0–1): AL109806.1, FAM209B, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1.
- chr22:41,229,510–41,240,931, 1 gene (within-gene range 0–1): CHADL.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 295 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:126,174,186–127,419,050, 11 genes, copy number 6 (within-gene range 1–6): RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1.
- chr8:127,079,874–127,092,600, 2 genes, copy number 6: PRNCR1, AC020688.1.
- chr8:127,578,473–130,443,674, 39 genes, copy number 6–10: AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1.
- chr8:132,120,859–138,497,261, 61 genes, copy number 5–11 (broad region; genes not listed).
- chr8:141,117,278–142,091,619, 20 genes, copy number 5 (within-gene range 1–5): DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1, AC104417.1, AC104417.2.
- chr8:143,915,153–144,314,720, 23 genes, copy number 5 (within-gene range 1–5): PLEC, MIR661, PARP10, GRINA, SPATC1, SMPD5, OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1, CYC1, SHARPIN, MAF1, WDR97, HGH1, TSSK5P, MROH1, BOP1, MIR7112, SCX, HSF1.
- chr10:132,397,168–132,420,953, 2 genes, copy number 5–7: PWWP2B, AL451069.2.
- chr16:89,166,383–89,169,147, 1 gene, copy number 6: LINC02138.
- chr16:89,195,761–89,201,651, 1 gene, copy number 10: SLC22A31.
- chr20:58,459,101–59,948,680, 40 genes, copy number 5: APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, PIEZO1P1, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D.
- chr20:62,122,461–63,739,103, 92 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr21:43,446,601–43,479,534, 3 genes, copy number 25–26: LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 15,707. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
